HCMI case HCM-BROD-0724-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e46ea440-c987-4c4f-8b7e-bacca42d32d8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 74.4 years (27,189 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Prior treatment: No; Sites of involvement: Brain, NOS / Lung, NOS.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Nivolumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 18 days; Days to treatment end: 353 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 472 days (1.3 years); Days to treatment end: 567 days (1.6 years); Treatment outcome: Treatment Ongoing.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Hormone Therapy, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C79.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: metastasis; Age at diagnosis: 74.4 years (27,191 days); Days to diagnosis: 2 days; Satellite nodule present: Indeterminate.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 7.

Follow-up (4 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Brain, NOS; Days to progression: 0 days.
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 0 days.
- Days to follow up: 570 days (1.6 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 297.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- KIT mutation, nos: Negative.
- NRAS mutation, nos: Negative.
- TP53 mutation, nos: Positive; Amino-acid change: C298T.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 163 cm; BMI: 25.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Melanoma.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0724-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0724-C43-06A-01-S1-HE: Section location: Top; Percent tumor cells: 88; Percent tumor nuclei: 97; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0724-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0724-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
